Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A80Y, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A80Y-01A (Primary Tumor).

Material: left adrenal

Date:

Grossly, 4.2 cm nodule sharply demarcated from the surrounding tissues. Histologically, the tumour has a mixture of alveolar and trabecular patterns. It is composed of large polygonal cells with round to ovoid nuclei. No increased mitotic activity or atypical mitotic figures are identified. Absence of necrosis. The capsule is infiltrated without destruction noted. The peri-adrenal adipose tissue is free of tumour. There is no evidence of vascular invasion. Tumour cells are strongly positive for chromogranin and synaptophysin whereas sustentacular cells at the periphery of neoplastic cell clusters are positive for S100 protein. Proliferative fraction (Ki-67) <1%.

Conclusion: Pheochromocytoma

Translated by

ICD-O-3
Pheochromocytoma NOS 8780/0
Site: ④ Adrenal gland NOS C74.9
JW 10/17/13

Source: NCI Genomic Data Commons file 0329bc56-2889-4e7d-867d-52619107b510 (TCGA-WB-A80Y.6CEDF687-932F-4ED7-9BD2-2C1B56507F17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).